HCMI case HCM-CSHL-0085-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/373c15fd-f995-419d-beef-951db2706411

Demographics
Sex at birth: male; Year of birth: 1961.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C24.1; Tissue or organ of origin: Ampulla of Vater; Site of resection or biopsy: Ampulla of Vater; Classification of tumor: primary; Age at diagnosis: 56.0 years (20,466 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 8; Lymph nodes tested: 30; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: No.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C77.2; Tissue or organ of origin: Ampulla of Vater; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 56.1 years (20,476 days); Days to diagnosis: 10 days; Residual disease: R0; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 8; Lymph nodes tested: 30; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 306, day 859.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 175 cm; BMI: 23.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0085-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0085-C24-01A-01-S1-HE: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 18; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0085-C24-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 58; Percent tumor nuclei: 90; Percent normal cells: 2; Percent necrosis: 20; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0085-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0085-C24-06A-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0085-C24-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0085-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0085-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0085-C24-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
